Somatic mutation profile of tumor specimen MP2PRT-PARGNB-TMP1-A (aliquot MP2PRT-PARGNB-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARGNB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,762 days).
Specimen MP2PRT-PARGNB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6c676c7-4624-44de-b6c9-f93640e6e7fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARGNB-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARGNB-NM1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b967e4a-6193-4385-ad89-2d937c2899cd

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3650G>A p.R1217K | Missense Mutation (SNP) | VAF 54/294 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs12298510, COSV53965202; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP4A | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 118/508 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs750384600, COSV99383131; called by muse, varscan2
- LRIG3 | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 133/502 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs754352982, COSV57863963; called by muse, mutect2, varscan2
- MCM3AP | c.2032C>T p.R678W | Missense Mutation (SNP) | VAF 96/307 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1054042539, COSV52439266; called by muse, varscan2
- FAM209A | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- MBD5 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- UTP20 | c.5224C>T p.P1742S | Missense Mutation (SNP) | VAF 94/393 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- BPI | c.351G>A p.K117= (on ENST00000262865; = p.K113= on NM_001725.3) | Silent (SNP) | VAF 70/330 reads (21%) | called by muse, varscan2
- GPR37 | c.1110C>T p.Y370= | Silent (SNP) | VAF 74/381 reads (19%) | catalogued as rs147406188, COSV58259202; called by muse, mutect2, varscan2
- SHC1 | c.9C>T p.L3= | Silent (SNP) | VAF 80/352 reads (23%) | catalogued as rs1389444459; called by muse, varscan2
- STING1 | c.453G>T p.G151= | Silent (SNP) | VAF 95/466 reads (20%) | called by muse, mutect2, varscan2
- UTP20 | c.5223C>T p.T1741= | Silent (SNP) | VAF 94/390 reads (24%) | called by muse, mutect2, varscan2
